Gene-level copy-number profile of tumor specimen TCGA-AR-A0U2-01A from TCGA case TCGA-AR-A0U2, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.6 years (17,390 days).
Specimen TCGA-AR-A0U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.90cc0bf8-5e04-4c34-bc2d-7d9d3b98569c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0U2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3a06a6d2-895e-428f-afcc-29ee1307443c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,747; copy number 2: 23,777; copy number 3: 16,227; copy number 4: 10,828; copy number 5: 3,421; copy number 6: 431; copy number 7: 514; copy number 8: 595; copy number 9: 71; copy number 10: 21; copy number 11: 6; copy number 12: 80; copy number 13: 13; copy number 14: 16; copy number 16: 15; copy number 17: 41; copy number 19: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0U2-01A-11D-A107-01): tumor purity 0.67, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,233 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:191,952,349–198,222,513, 187 genes, copy number 5 (broad region; genes not listed).
- chr7:17,679,549–64,836,882, 892 genes, copy number 5–6 (broad region; genes not listed).
- chr8:35,862,123–37,779,768, 34 genes, copy number 5–9: AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP.
- chr8:71,197,433–71,702,786, 3 genes, copy number 6 (within-gene range 4–6): EYA1, TRAPPC2P2, AC009446.1.
- chr8:78,268,637–83,100,846, 88 genes, copy number 5–8 (broad region; genes not listed).
- chr8:84,828,573–135,742,495, 739 genes, copy number 6–19 (within-gene range 4–19) (broad region; genes not listed).
- chr8:135,977,329–135,980,588, 1 gene, copy number 8: AC103955.1.
- chr9:37,477,149–43,045,120, 160 genes, copy number 5 (broad region; genes not listed).
- chr11:16,484,084–24,262,218, 145 genes, copy number 5 (broad region; genes not listed).
- chr11:26,559,032–47,715,389, 333 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:60,813,932–61,127,852, 17 genes, copy number 9–10: AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5.
- chr11:69,294,151–72,674,591, 120 genes, copy number 7 (broad region; genes not listed).
- chr11:75,815,210–76,144,232, 1 gene, copy number 7 (within-gene range 2–7): UVRAG.
- chr11:75,911,204–77,821,017, 44 genes, copy number 7: PPP1R1AP1, AP003168.2, RNA5SP344, AP003168.1, AP002340.1, WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1.
- chr11:79,966,805–83,039,115, 25 genes, copy number 8 (within-gene range 2–8): AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2.
- chr12:41,188,320–44,389,762, 48 genes, copy number 5 (within-gene range 4–5): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1.
- chr16:29,618,785–35,912,516, 399 genes, copy number 8 (broad region; genes not listed).
- chr18:7,566,782–8,406,861, 1 gene, copy number 5 (within-gene range 3–5): PTPRM.
- chr18:7,995,570–8,155,070, 4 genes, copy number 5: U3, AP005900.1, AC006566.2, AC006566.1.
- chr18:11,447,756–12,725,740, 57 genes, copy number 5 (within-gene range 3–5): AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2.
- chr18:26,226,445–26,391,685, 1 gene, copy number 9 (within-gene range 3–9): TAF4B.
- chr18:26,348,347–28,177,946, 29 genes, copy number 9: AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.
- chr18:48,475,487–49,851,059, 40 genes, copy number 7: RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1.
- chr18:49,871,555–49,871,666, 1 gene, copy number 7: Y_RNA.
- chr18:58,671,465–58,754,477, 2 genes, copy number 5 (within-gene range 3–5): MALT1, AC104365.1.
- chr18:58,752,179–65,448,167, 102 genes, copy number 5 (broad region; genes not listed).
- chr18:76,978,827–77,133,683, 1 gene, copy number 11 (within-gene range 3–11): MBP.
- chr18:77,042,864–80,247,514, 64 genes, copy number 8–11 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).
- chr21:43,865,223–46,570,015, 126 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:46,360,834–50,801,309, 111 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,211. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
